Somatic mutation profile of tumor specimen C3N-02244-72 (aliquot CPT0128960006) from CPTAC case C3N-02244, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; Tumor grade: G2.
Specimen C3N-02244-72: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 161735d6-59fe-49b7-924b-22559e0ccc0f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02244-31 (Blood Derived Normal), aliquot CPT0130790002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/110ddd08-62dc-4dac-8a96-e245f233c6d4

The open-access MAF lists 55 somatic variants for this specimen: 35 protein-altering or splice-affecting, 14 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 14, Intron 5, Nonsense Mutation 3, 5'UTR 1, Splice Region 1, Splice Site 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.274G>T p.D92Y | Missense Mutation (SNP) | VAF 57/284 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1554898067, CM1111457, COSV64291669, COSV64295080, COSV64295612; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARID1A | c.4024C>T p.Q1342* | Nonsense Mutation (SNP) | VAF 25/162 reads (15%) | catalogued as COSV61381745; called by muse, mutect2, varscan2
- DEF6 | c.1850C>T p.A617V | Missense Mutation (SNP) | VAF 8/113 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.005); catalogued as rs866047183; called by muse, mutect2
- DYRK1A | c.1042G>T p.G348W | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100117534, COSV58294108; called by muse, mutect2
- EFNB3 | c.707C>T p.A236V | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.87); PolyPhen benign (0.09); catalogued as rs774270981; called by muse, mutect2, varscan2
- EIF3A | c.3007G>A p.D1003N | Missense Mutation (SNP) | VAF 40/619 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.035); catalogued as COSV100974519; called by muse, mutect2
- ERAS | c.305A>T p.H102L | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.251); catalogued as COSV99504866; called by muse, mutect2, varscan2
- IQSEC2 | c.3212G>A p.R1071H (on ENST00000642864 / NM_001111125.3; = p.R866H on NM_015075.2) | Missense Mutation (SNP) | VAF 35/279 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.209); catalogued as COSV64725860; called by muse, mutect2, varscan2
- KLHL6 | c.1804G>A p.V602I | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.899); catalogued as rs773490211, COSV58065910; called by muse, mutect2
- MED12 | c.67G>T p.D23Y | Missense Mutation (SNP) | VAF 20/268 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61334558; called by muse, mutect2
- NCOA1 | c.3085C>T p.R1029* | Nonsense Mutation (SNP) | VAF 38/367 reads (10%) | catalogued as COSV56045979; called by muse, mutect2, varscan2
- OR2B3 | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 7/182 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); catalogued as rs761688447, COSV65851237; called by muse, mutect2
- PDIA4 | c.1495C>T p.L499F (on ENST00000286091 / NM_001371244.1; = p.L498F on NM_004911.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/198 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.033); catalogued as COSV53725514; called by muse, mutect2
- PPP2R2B | c.854C>T p.S285L (on ENST00000394409; = p.S351L on NM_181674.2) | Missense Mutation (SNP) | VAF 12/234 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs1277397270, COSV60751285; called by muse, mutect2
- RNF138 | c.622G>A p.V208I | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0.074); catalogued as rs1309524763, COSV99857532; called by muse, mutect2
- TRRAP | c.6248C>G p.S2083C (on ENST00000359863 / NM_001244580.1; = p.S2065C on NM_003496.3) | Missense Mutation (SNP) | VAF 22/403 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.19); catalogued as COSV62854989; called by muse, mutect2
- TSPAN10 | c.79C>T p.R27C | Missense Mutation (SNP) | VAF 14/231 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs371270497; called by muse, mutect2
- ZBTB2 | c.1424T>G p.V475G | Missense Mutation (SNP) | VAF 28/309 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.208); catalogued as rs776038078, COSV57312798; called by muse, mutect2
- ADGRL3 | c.4416G>T p.L1472F (on ENST00000506720 / NM_001322402.2; = p.L1361F on NM_015236.6) | Missense Mutation (SNP) | VAF 19/403 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.974); called by muse, mutect2
- ANO2 | c.2915G>A p.R972K (on ENST00000356134 / NM_001278597.3; = p.R976K on NM_001278596.3) | Missense Mutation (SNP) | VAF 46/402 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- HMGN4 | c.184G>A p.A62T | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAP3K10 | c.2302G>A p.E768K | Missense Mutation (SNP) | VAF 7/104 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.033); called by muse, mutect2
- MUC19 | c.858C>A p.G286= | Splice Region (SNP) | VAF 9/152 reads (6%) | called by muse, mutect2
- PDZD4 | c.1276C>T p.R426C | Missense Mutation (SNP) | VAF 25/236 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- REV3L | c.195C>G p.Y65* | Nonsense Mutation (SNP) | VAF 22/231 reads (10%) | called by muse, mutect2
- SLC32A1 | c.1028C>T p.T343M | Missense Mutation (SNP) | VAF 14/210 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- SLC47A1 | c.330_332dup p.K110_H111insQ | In Frame Ins (INS) | VAF 10/118 reads (8%) | called by mutect2, pindel
- SOCS7 | c.872C>A p.S291Y | Missense Mutation (SNP) | VAF 32/313 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- TAOK3 | c.737+1del p.X246_splice | Splice Site (DEL) | VAF 14/140 reads (10%) | called by mutect2, pindel, varscan2
- TFIP11 | c.364G>A p.G122S | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT tolerated (0.48); PolyPhen benign (0.073); called by muse, mutect2
- UGDH | c.283A>C p.T95P | Missense Mutation (SNP) | VAF 35/330 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- VCPIP1 | c.2573G>T p.G858V | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- VWA5B2 | c.3079C>T p.P1027S | Missense Mutation (SNP) | VAF 9/218 reads (4%) | SIFT tolerated (0.49); PolyPhen benign (0.005); called by muse, mutect2
- WNK3 | c.3851C>A p.T1284N | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.028); called by muse, mutect2
- ZNF469 | c.4681G>T p.A1561S (on ENST00000437464; = p.A1589S on NM_001367624.2) | Missense Mutation (SNP) | VAF 83/846 reads (10%) | SIFT tolerated (0.72); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ABCC6 | c.231C>T p.F77= | Silent (SNP) | VAF 44/535 reads (8%) | catalogued as rs745917696; called by muse, mutect2, varscan2
- ALDH1A3 | c.1437C>T p.G479= | Silent (SNP) | VAF 18/178 reads (10%) | called by muse, mutect2
- APOA4 | c.444G>A p.T148= | Silent (SNP) | VAF 12/119 reads (10%) | catalogued as rs762145587; called by muse, mutect2, varscan2
- B3GAT1 | c.471C>T p.D157= | Silent (SNP) | VAF 26/348 reads (7%) | catalogued as rs761344039, COSV56998057, COSV56998905; called by muse, mutect2
- FNIP2 | c.315C>T p.S105= | Silent (SNP) | VAF 34/291 reads (12%) | called by muse, mutect2, varscan2
- MFSD2B | c.177C>T p.S59= | Silent (SNP) | VAF 12/116 reads (10%) | catalogued as rs372274973; called by muse, mutect2, varscan2
- OPTN | c.933G>A p.K311= | Silent (SNP) | VAF 28/298 reads (9%) | called by muse, mutect2
- PLD6 | c.573C>T p.D191= | Silent (SNP) | VAF 28/320 reads (9%) | catalogued as rs371619441; called by muse, mutect2
- RBM20 | c.915A>G p.K305= | Silent (SNP) | VAF 32/441 reads (7%) | called by muse, mutect2
- SI | c.5364G>A p.T1788= | Silent (SNP) | VAF 19/173 reads (11%) | catalogued as rs778515268; called by muse, mutect2, varscan2
- SP6 | c.561C>T p.D187= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as rs760116499; called by mutect2, varscan2
- SPRED1 | c.1200C>T p.F400= | Silent (SNP) | VAF 32/205 reads (16%) | called by muse, mutect2, varscan2
- SPTBN2 | c.4815C>T p.G1605= | Silent (SNP) | VAF 32/494 reads (6%) | catalogued as rs527634722; called by muse, mutect2
- USP51 | c.231C>T p.S77= | Silent (SNP) | VAF 39/377 reads (10%) | called by muse, mutect2, varscan2
- DST | c.4296+4086G>T | Intron (SNP) | VAF 20/242 reads (8%) | catalogued as COSV99755775; called by muse, mutect2
- LAMA1 | c.233-36C>T | Intron (SNP) | VAF 24/331 reads (7%) | catalogued as rs369661634; called by muse, mutect2
- PIP4K2A | c.640-1135C>T | Intron (SNP) | VAF 10/136 reads (7%) | catalogued as rs188535082; called by muse, mutect2
- QKI | c.935-746T>C | Intron (SNP) | VAF 11/98 reads (11%) | called by muse, mutect2, varscan2
- RPL5 | c.528-109G>A | Intron (SNP) | VAF 14/233 reads (6%) | catalogued as rs371558666; called by muse, mutect2
- TMPRSS5 | c.-33C>T | 5'UTR (SNP) | VAF 8/134 reads (6%) | catalogued as rs1434302540; called by muse, mutect2
